Surgical pathology report (de-identified scan), TCGA case TCGA-29-1771, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1771-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1771

Surg Path

CLINICAL HISTORY:

Malignant neoplasm of the ovary.

GROSS EXAMINATION:

A. "Right tube and ovary (AF1)". Received fresh and placed in formalin is a 36.4 gram, 5.2 x 5 x 2 cm ovary with contiguous 2 cm segment of fallopian tube. The ovary is remarkable for multiple papillary excrescences covering the entire external surface. Sectioning through the specimen demonstrates a friable pink-tan cut surface with focal areas of nodularity up to 1 cm. Representative sections are submitted as frozen section as AF1.

BLOCK SUMMARY:

A1- AF1.

A2-A4- representative sections of ovary.

A5- largest nodule.

A6- presumed fallopian tube.

B. "Omentum". Received fresh and placed in formalin is an 11 x 5 x 1.3 cm fragment of tan-yellow fibroadipose tissue. There is a 5 x 3 x 1.3 cm area of ill defined firmness within the adipose tissue. However, no discrete masses are identified. Representative sections are submitted in blocks B1-B3.

C. "Right lower quadrant nodule". Received fresh and placed in formalin is a 13 x 4 x 1.6 cm fragment of tan-yellow fibroadipose tissue. Sectioning through the specimen demonstrates a 2 x 1.2 x 0.8 cm firm, ill defined, tan-white nodule. Representative sections are submitted in blocks C1-C5.

D. "Left tube and ovary". Received fresh and placed in formalin, 4 x 2.5 x 1.8 cm ovary with adjacent 4 cm portion of fallopian tube. The ovary is remarkable for a firm, white-tan cut surface with multiple pink papillary excrescences covering the exterior of the ovary. The fallopian tube is remarkable for a 2.6 x 1.8 x 1.4 cm paratubal cyst. The remainder of the cut surface is remarkable.

BLOCK SUMMARY:

D1-D4- representative sections of ovary

D5- representative sections of fallopian tube

INTRA OPERATIVE CONSULTATION:

A. "Right tube and ovary": AF1- papillary serous carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Salpingo-oophorectomy and partial omentectomy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [redacted] as required for accreditation by the [redacted]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section,

[page 2 of 2]
TCGA-29-1771

past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "RIGHT TUBE AND OVARY (AF1)":

RIGHT OVARY: CARCINOMA.

TYPE: PAPILLARY SEROUS ADENOCARCINOMA

FIGO GRADE: 2/3

TUMOR SIZE: 5.2 X 5 X 2 CM.

WEIGHT: 36 GRAMS

SEROUSA: POSITIVE FOR TUMOR.

RIGHT FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

B. "OMENTUM":

ADIPOSE TISSUE WITH METASTATIC SEROUS ADENOCARCINOMA.

MAXIMUM TUMOR SIZE: 5 CM.

VASCULAR INVASION: PRESENT

C. "RIGHT LOWER QUADRANT NODULE":

SEROUS ADENOCARCINOMA.

MAXIMUM TUMOR SIZE 2 CM.

D. "LEFT TUBE AND OVARY":

LEFT OVARY:

TYPE: PAPILLARY SEROUS ADENOCARCINOMA

FIGO GRADE: 2/3

TUMOR SIZE: 4 X 2.5 X 1.8 CM.

SEROUSA: POSITIVE FOR CARCINOMA

LEFT FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

COMMENT: The tumor in both the ovaries has some areas with the growth pattern of a borderline serous tumor, along with invasive adenocarcinoma. Immunoperoxidase stains of the tumor in part B are positive for CK7, Berep4, WT1, and CA125, are focally positive for CK20, and are negative for CDX2 and calretinin.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 64ee968d-0968-4001-81e2-0751451bb4f8 (TCGA-29-1771.005CA6AA-3326-4B7C-B8A5-86A6DFB70A93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).